Somatic mutation profile of tumor specimen TARGET-30-PAPUJU-01A (aliquot TARGET-30-PAPUJU-01A-01D) from TARGET case TARGET-30-PAPUJU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.6 years (954 days).
Specimen TARGET-30-PAPUJU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3ad6e21-fd98-46fd-bc3e-c13e665a0126.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPUJU-10A (Blood Derived Normal), aliquot TARGET-30-PAPUJU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/288b24cb-4c7c-4dbf-979f-4b6b59ae55c4

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1001308957, COSV60916710; called by muse, mutect2
- ALOX15B | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV101205541; called by muse, mutect2
- SEMA3A | c.2178G>A p.W726* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV54866957; called by muse, mutect2
- RRAGA | c.723C>G p.S241R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TGFB2 | c.959G>C p.R320P | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TXNDC11 | c.1280T>A p.V427E (on ENST00000356957 / NM_001303447.2; = p.V400E on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2
- GALNT5 | c.144C>T p.D48= | Silent (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- MX2 | c.447C>T p.I149= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs771953735, COSV58096517; called by muse, mutect2, varscan2
